Somatic mutation profile of tumor specimen TCGA-G7-6789-01A (aliquot TCGA-G7-6789-01A-11D-1961-08) from TCGA case TCGA-G7-6789, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 53.6 years (19,593 days).
Specimen TCGA-G7-6789-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92f6fcae-c946-4212-8090-4c5ac86ab59b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G7-6789-10A (Blood Derived Normal), aliquot TCGA-G7-6789-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a57bea3-0320-48f2-a924-2aa928d2f503

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 11, Silent 8, Frame Shift Del 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 21/29 reads (72%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- ALPG | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs145892470; called by muse, mutect2, varscan2
- CCDC142 | c.1639G>A p.E547K (on ENST00000393965 / NM_001365575.2; = p.E540K on NM_032779.4) | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV50688307; called by muse, mutect2, varscan2
- CFAP300 | c.334C>G p.H112D | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71570564, COSV71570659; called by muse, mutect2, varscan2
- GSTK1 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 90/451 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs753046041, COSV64423946; called by muse, mutect2, varscan2
- PRRC2B | c.2899G>C p.G967R | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV61933654; called by muse, mutect2, varscan2
- SLC26A3 | c.1719A>C p.K573N | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60638569; called by muse, mutect2, varscan2
- SLC6A14 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 74/124 reads (60%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV64146030, COSV64147554; called by muse, mutect2, varscan2
- TDRD5 | c.1589A>C p.H530P | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV54238677; called by muse, mutect2, varscan2
- TNNI3K | c.1931T>G p.I644S | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0.131); catalogued as COSV58545167; called by muse, mutect2, varscan2
- TRHDE | c.893A>G p.Y298C | Missense Mutation (SNP) | VAF 93/243 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1435516049, COSV53831798; called by muse, mutect2, varscan2
- ZNF684 | c.451A>G p.R151G | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV65518810; called by muse, mutect2, varscan2
- POLR1B | c.739_746del p.L247Gfs*5 | Frame Shift Del (DEL) | VAF 38/159 reads (24%) | called by mutect2, pindel, varscan2
- PTPRC | c.1145del p.S382Ifs*28 | Frame Shift Del (DEL) | VAF 21/206 reads (10%) | called by mutect2, pindel, varscan2
- SAV1 | c.420dup p.D141* | Frame Shift Ins (INS) | VAF 30/48 reads (63%) | called by mutect2, varscan2
- AMPD1 | c.1674C>G p.S558= | Silent (SNP) | VAF 44/145 reads (30%) | catalogued as COSV62414958; called by muse, mutect2, varscan2
- ANKS1A | c.2946C>A p.I982= | Silent (SNP) | VAF 65/99 reads (66%) | catalogued as COSV64458655; called by muse, mutect2, varscan2
- CCL3L3 | c.93G>A p.P31= | Silent (SNP) | VAF 82/925 reads (9%) | catalogued as rs1327236999; called by muse, mutect2
- DNAH1 | c.9418C>T p.L3140= | Silent (SNP) | VAF 34/50 reads (68%) | catalogued as rs746475963, COSV70226166; called by muse, mutect2, varscan2
- FAR2 | c.1291T>C p.L431= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs758118238, COSV51723134; called by muse, mutect2, varscan2
- FZD1 | c.789G>T p.P263= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs752405110, COSV55308793, COSV55313838; called by muse, mutect2, varscan2
- RNF213 | c.13842C>G p.G4614= | Silent (SNP) | VAF 87/156 reads (56%) | catalogued as rs971228610, COSV60389597; called by muse, mutect2, varscan2
- RPRD1A | c.657G>A p.A219= | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as rs202026701, COSV59822393; called by muse, mutect2, varscan2
